Somatic mutation profile of tumor specimen TCGA-66-2777-01A (aliquot TCGA-66-2777-01A-01D-1267-08) from TCGA case TCGA-66-2777, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71.4 years (26,085 days).
Specimen TCGA-66-2777-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a514887-35d3-4a08-97f1-27e28cc7af4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2777-11A (Solid Tissue Normal), aliquot TCGA-66-2777-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35eb5e2a-d3a1-442d-a7fd-fecc7c51621f

The open-access MAF lists 181 somatic variants for this specimen: 133 protein-altering or splice-affecting, 45 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 45, Nonsense Mutation 8, Frame Shift Del 6, Splice Site 2, 3'UTR 1, Intron 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 42/152 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.3484C>A p.P1162T | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as COSV52223229; called by muse, mutect2, varscan2
- ADAMTS16 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 102/508 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs752666810, COSV56987513, COSV57008464; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2372C>T p.T791M | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.509); catalogued as rs144077662, COSV54450723; called by muse, mutect2, varscan2
- ADGRG4 | c.3262A>G p.T1088A | Missense Mutation (SNP) | VAF 245/505 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs1336728642, COSV99794750; called by muse, mutect2, varscan2
- AGTR1 | c.569C>A p.T190N | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.062); catalogued as COSV62558465; called by muse, mutect2
- AHCTF1 | c.2156A>G p.D719G (on ENST00000366508; = p.D693G on NM_015446.5) | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58250941; called by muse, mutect2, varscan2
- ALS2 | c.2090A>T p.E697V | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51887849; called by muse, mutect2, varscan2
- AMN | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV54486929; called by muse, mutect2, varscan2
- ANO5 | c.533G>T p.S178I | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV61085649; called by muse, varscan2
- ARAP2 | c.3708C>G p.N1236K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV100394437, COSV58287463; called by muse, mutect2, varscan2
- ARHGEF26 | c.1414A>T p.S472C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as COSV62847070; called by muse, mutect2
- ARL6 | c.227A>G p.Y76C | Missense Mutation (SNP) | VAF 101/264 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60117750; called by muse, mutect2, varscan2
- ATP10A | c.3119A>T p.Q1040L | Missense Mutation (SNP) | VAF 120/603 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV63518235; called by muse, mutect2, varscan2
- ATP11C | c.1172G>C p.G391A | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.948); catalogued as COSV59565218; called by muse, mutect2, varscan2
- ATP5MC2 | c.421A>G p.M141V | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs760738232, COSV58601503; called by muse, mutect2, varscan2
- ATP8A2 | c.1109A>T p.Y370F | Missense Mutation (SNP) | VAF 90/355 reads (25%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.987); catalogued as COSV54955078; called by muse, mutect2, varscan2
- BTBD8 | c.1023G>T p.W341C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs150938488, COSV61546478; called by muse, mutect2, varscan2
- C16orf90 | c.243C>G p.H81Q (on ENST00000399645 / NM_001353385.2; = p.H72Q on NM_001080524.2) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.466); catalogued as COSV101290953; called by muse, varscan2
- CBLN2 | c.215C>A p.P72Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373648257, COSV54052134; called by muse, varscan2
- CDH13 | c.1474G>T p.V492L | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV51825313, COSV51836932; called by muse, varscan2
- CDH9 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.215); catalogued as COSV50295224; called by muse, mutect2, varscan2
- CDK19 | c.629A>G p.H210R | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV60449825; called by muse, mutect2, varscan2
- CFHR4 | c.1479G>C p.Q493H (on ENST00000367416 / NM_001201551.2; = p.Q247H on NM_006684.5) | Missense Mutation (SNP) | VAF 132/432 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs774683559, COSV52229713; called by muse, mutect2, varscan2
- CHD4 | c.4576A>G p.K1526E (on ENST00000357008 / NM_001363606.2; = p.K1539E on NM_001273.5) | Missense Mutation (SNP) | VAF 88/349 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.969); catalogued as COSV58902247; called by muse, mutect2, varscan2
- CHSY3 | c.2506G>T p.V836F | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59278250; called by muse, mutect2, varscan2
- COL13A1 | c.1007G>A p.G336E (on ENST00000398978 / NM_001130103.2; = p.G279E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62570583; called by muse, mutect2, varscan2
- COL15A1 | c.3119G>T p.G1040V | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66645687; called by muse, mutect2, varscan2
- CRTC2 | c.1936G>C p.A646P | Missense Mutation (SNP) | VAF 73/489 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.29); catalogued as COSV57843275; called by muse, mutect2, varscan2
- CST1 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs142792460; called by muse, mutect2, varscan2
- CXCR4 | c.227A>G p.Y76C | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV54010069; called by muse, mutect2, varscan2
- CYP4A22 | c.387C>G p.Y129* | Nonsense Mutation (SNP) | VAF 38/116 reads (33%) | catalogued as COSV53740642; called by muse, mutect2, varscan2
- DCAF12L1 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV64421939; called by muse, mutect2, varscan2
- DCAF12L2 | c.891G>T p.R297S | Missense Mutation (SNP) | VAF 96/236 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV63581998; called by muse, mutect2, varscan2
- DDC | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV63565408; called by muse, mutect2, varscan2
- DENND2B | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58204178; called by muse, mutect2, varscan2
- DNAH5 | c.11842G>A p.E3948K | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV54229216; called by muse, mutect2, varscan2
- DSG2 | c.2633C>T p.S878L | Missense Mutation (SNP) | VAF 77/296 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55199752; called by muse, mutect2, varscan2
- DYRK1B | c.947C>G p.S316C | Missense Mutation (SNP) | VAF 71/160 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV59913851; called by muse, mutect2, varscan2
- ECRG4 | c.301A>T p.I101F | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV53001013; called by muse, mutect2, varscan2
- ENPEP | c.1837G>T p.G613* | Nonsense Mutation (SNP) | VAF 30/116 reads (26%) | catalogued as COSV54451938, COSV99488279; called by muse, mutect2, varscan2
- EPB41L5 | c.1533G>T p.Q511H | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV55352913; called by muse, mutect2
- ERCC4 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV61312258; called by muse, mutect2, varscan2
- ERI2 | c.435A>T p.K145N | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV55501755; called by muse, mutect2, varscan2
- FAM135B | c.2138T>C p.V713A | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV52728926; called by muse, mutect2, varscan2
- FBXW5 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs768536340, COSV56403138; called by muse, mutect2, varscan2
- FLNA | c.2023-2A>C p.X675_splice | Splice Site (SNP) | VAF 80/135 reads (59%) | catalogued as COSV61044165; called by muse, mutect2, varscan2
- GABRA2 | c.697A>T p.S233C | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV62915523; called by muse, mutect2, varscan2
- GALNT10 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 114/387 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51727529; called by muse, mutect2, varscan2
- GDF5 | c.322C>A p.P108T | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65501818; called by muse, mutect2, varscan2
- GDPD5 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1405132857, COSV61126659; called by muse, mutect2, varscan2
- GNAS | c.822G>C p.K274N | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV55677845; called by muse, mutect2, varscan2
- GTPBP1 | c.1084A>T p.I362L | Missense Mutation (SNP) | VAF 84/969 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV53285163; called by muse, mutect2
- GUCY2C | c.2141A>G p.E714G | Missense Mutation (SNP) | VAF 78/333 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV53790976; called by muse, mutect2, varscan2
- HCN1 | c.2103del p.A702Rfs*78 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as COSV57518789, COSV57525369; called by mutect2, pindel, varscan2
- HTR1E | c.758C>A p.T253N | Missense Mutation (SNP) | VAF 70/643 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.727); catalogued as COSV59508425; called by muse, mutect2, varscan2
- IGF2R | c.2773C>G p.Q925E | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.043); catalogued as COSV100807975, COSV63629524; called by muse, mutect2, varscan2
- IL27 | c.110A>T p.Q37L | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV63559687; called by muse, mutect2, varscan2
- JAKMIP3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374779116; called by muse, mutect2, varscan2
- KEAP1 | c.671C>A p.S224Y | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV50289021, COSV50291504; called by muse, mutect2, varscan2
- KRIT1 | c.699G>C p.L233F | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as CD001474, COSV60668422; called by muse, mutect2
- LAMA1 | c.6736A>G p.T2246A | Missense Mutation (SNP) | VAF 159/709 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.31); catalogued as COSV67538160; called by muse, mutect2, varscan2
- LRP2 | c.12916G>A p.E4306K | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.44); catalogued as COSV55556204; called by muse, mutect2, varscan2
- LRP2 | c.9996T>A p.Y3332* | Nonsense Mutation (SNP) | VAF 71/269 reads (26%) | catalogued as COSV55556212, COSV55562907; called by muse, mutect2, varscan2
- LRP6 | c.1904T>G p.L635W | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53788291; called by muse, mutect2
- LRRTM3 | c.759C>A p.S253R | Missense Mutation (SNP) | VAF 94/411 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.281); catalogued as rs781161525, COSV63666255; called by muse, mutect2, varscan2
- LTBP2 | c.3584G>A p.S1195N | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV56208952; called by muse, mutect2, varscan2
- MAGEA4 | c.-137G>T | Splice Region (SNP) | VAF 38/79 reads (48%) | catalogued as COSV99367368; called by muse, mutect2
- MTCL1 | c.3376G>T p.G1126* (on ENST00000306329 / NM_001378206.1; = p.G807* on NM_015210.4) | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | catalogued as COSV60406752; called by muse, mutect2
- NCEH1 | c.938C>T p.S313L (on ENST00000538775; = p.S273L on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/430 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as COSV56434963; called by muse, mutect2
- NCKAP5L | c.2509A>G p.K837E | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as COSV60130072; called by muse, mutect2, varscan2
- NLRP6 | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 84/392 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56460004; called by muse, varscan2
- NTRK1 | c.1357C>A p.P453T | Missense Mutation (SNP) | VAF 136/360 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV62325984; called by muse, mutect2, varscan2
- NTRK3 | c.369T>G p.F123L | Missense Mutation (SNP) | VAF 54/511 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58124752; called by muse, mutect2
- OR12D2 | c.868A>T p.T290S | Missense Mutation (SNP) | VAF 77/340 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.125); catalogued as COSV65828230; called by muse, mutect2, varscan2
- OR2T12 | c.137T>A p.L46Q | Missense Mutation (SNP) | VAF 40/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58777755; called by muse, mutect2, varscan2
- OR4C11 | c.253T>A p.S85T | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.352); catalogued as COSV56353607; called by muse, mutect2, varscan2
- OR4L1 | c.796G>C p.A266P | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV59850177; called by muse, mutect2, varscan2
- OR5T3 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57380989; called by muse, mutect2, varscan2
- OR6C65 | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 78/326 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.476); catalogued as COSV101110210, COSV65568726; called by muse, mutect2, varscan2
- OR8D4 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 115/564 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV58430549; called by muse, mutect2, varscan2
- PCDH15 | c.4817C>A p.A1606E (on ENST00000644397 / NM_001354429.2; = p.A1548E on NM_001142771.2) | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs777147348, COSV64698991; called by muse, mutect2, varscan2
- PCNX3 | c.3708G>A p.W1236* | Nonsense Mutation (SNP) | VAF 23/106 reads (22%) | catalogued as COSV63137145; called by muse, mutect2, varscan2
- PEG3 | c.2431G>C p.D811H | Missense Mutation (SNP) | VAF 62/660 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.299); catalogued as COSV55626223, COSV55635648; called by muse, mutect2
- PEG3 | c.875T>A p.M292K | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV55635664; called by muse, mutect2
- PHGDH | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 110/260 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65571113; called by muse, mutect2, varscan2
- PI4KA | c.3511A>G p.K1171E | Missense Mutation (SNP) | VAF 211/526 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV55412548; called by muse, mutect2, varscan2
- PKHD1L1 | c.10135G>A p.A3379T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV65744279; called by muse, mutect2, varscan2
- PRKN | c.412+2T>A p.X138_splice | Splice Site (SNP) | VAF 38/262 reads (15%) | catalogued as COSV58230500; called by muse, mutect2, varscan2
- PSD | c.1900C>T p.Q634* | Nonsense Mutation (SNP) | VAF 9/81 reads (11%) | catalogued as COSV50046601; called by muse, mutect2
- RAB3GAP1 | c.973G>T p.G325C | Missense Mutation (SNP) | VAF 88/354 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV51483003; called by muse, varscan2
- RBCK1 | c.326G>A p.R109Q (on ENST00000356286 / NM_031229.4; = p.R67Q on NM_006462.6) | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs568820415, COSV62292114, COSV62292450; called by muse, mutect2, varscan2
- REG1A | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 58/276 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.866); catalogued as rs267599471, COSV52069911; called by muse, mutect2, varscan2
- RNASE13 | c.203G>T p.C68F | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs922146878, COSV58794357, COSV58794919; called by muse, mutect2, varscan2
- RYR2 | c.11764G>T p.E3922* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV63688696; called by mutect2, varscan2
- SCAF4 | c.431T>A p.V144E | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54587759; called by muse, mutect2, varscan2
- SEPTIN12 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs764712886, COSV51617393; called by muse, mutect2, varscan2
- SHPRH | c.366G>T p.Q122H | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV51611139; called by muse, mutect2, varscan2
- SLC20A2 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV60603948; called by muse, mutect2
- SLC24A5 | c.905A>G p.D302G | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as COSV51048272; called by muse, mutect2, varscan2
- SPINT4 | c.212T>A p.F71Y | Missense Mutation (SNP) | VAF 71/312 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54142811; called by muse, mutect2, varscan2
- SPIRE2 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as rs574309721, COSV54528691; called by muse, mutect2
- SRGAP1 | c.42A>G p.I14M | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV61898727; called by muse, mutect2
- STARD7 | c.267G>T p.R89S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV61525911; called by muse, mutect2
- STARD8 | c.2491G>T p.A831S | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.364); catalogued as COSV52927439; called by muse, mutect2, varscan2
- STAU2 | c.979G>T p.V327F (on ENST00000524300 / NM_001164380.2; = p.V295F on NM_014393.2) | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV63308558; called by muse, mutect2, varscan2
- STK32B | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51490154; called by muse, mutect2, varscan2
- STYXL2 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs267598150, COSV54805349, COSV54805725; called by muse, mutect2, varscan2
- SUN3 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV52051051, COSV99813712; called by muse, mutect2, varscan2
- SYNE1 | c.1785G>T p.R595S (on ENST00000367255 / NM_182961.4; = p.R602S on NM_033071.3) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); catalogued as COSV54998207; called by muse, mutect2, varscan2
- TBC1D20 | c.718G>C p.D240H | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62612867; called by muse, mutect2, varscan2
- TEX55 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.414); catalogued as COSV55211342; called by muse, mutect2, varscan2
- TMEM52B | c.364C>A p.H122N (on ENST00000381923 / NM_001079815.1; = p.H102N on NM_153022.4) | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.445); catalogued as COSV53728585; called by muse, mutect2, varscan2
- TRAT1 | c.62C>G p.A21G | Missense Mutation (SNP) | VAF 130/427 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); catalogued as COSV55468936; called by muse, mutect2, varscan2
- TRMT13 | c.1259G>C p.S420T | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61583151; called by muse, mutect2, varscan2
- VPS50 | c.2173G>A p.G725R | Missense Mutation (SNP) | VAF 78/259 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59919011; called by muse, mutect2, varscan2
- VWF | c.8305G>A p.D2769N | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV54622282; called by muse, mutect2, varscan2
- ZFC3H1 | c.892G>C p.A298P | Missense Mutation (SNP) | VAF 53/244 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV66433147; called by muse, mutect2, varscan2
- ZNF451 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62597907; called by muse, mutect2
- ZNF521 | c.2855A>G p.H952R | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100831612; called by muse, mutect2, varscan2
- ZNF577 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 89/313 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as rs375998998; called by muse, mutect2, varscan2
- ZNF618 | c.2503G>T p.E835* (on ENST00000374126 / NM_001318042.2; = p.E742* on NM_133374.2) | Nonsense Mutation (SNP) | VAF 49/177 reads (28%) | catalogued as COSV55922432; called by muse, mutect2, varscan2
- ZYG11B | c.1408G>T p.A470S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.017); catalogued as COSV53753508, COSV99596789; called by muse, mutect2, varscan2
- GPANK1 | c.514del p.V172Sfs*4 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | called by mutect2, pindel, varscan2
- KCNN4 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR56B1 | c.12_13del p.M4Ifs*9 | Frame Shift Del (DEL) | VAF 38/144 reads (26%) | called by mutect2, pindel, varscan2
- POLR2A | c.3226T>C p.F1076L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SERPINB11 | c.1142del p.N381Tfs*25 | Frame Shift Del (DEL) | VAF 64/388 reads (16%) | called by mutect2, pindel, varscan2
- SPIDR | c.254A>G p.Q85R | Missense Mutation (SNP) | VAF 87/327 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TREX2 | c.32_35del p.S11Ffs*22 | Frame Shift Del (DEL) | VAF 60/340 reads (18%) | called by pindel, varscan2
- TRGV8 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- UTY | c.2792del p.F931Sfs*7 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- ZNF658 | c.1409A>T p.N470I | Missense Mutation (SNP) | VAF 91/505 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, varscan2
- ABCA12 | c.3390C>T p.I1130= (on ENST00000272895 / NM_173076.3; = p.I812= on NM_015657.3) | Silent (SNP) | VAF 42/204 reads (21%) | catalogued as COSV55961218; called by muse, mutect2, varscan2
- APBA2 | c.204C>T p.P68= | Silent (SNP) | VAF 56/461 reads (12%) | catalogued as rs1179351862, COSV68791858; called by muse, mutect2, varscan2
- CDH10 | c.1632T>A p.T544= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV52582941; called by muse, mutect2, varscan2
- CHGB | c.879C>T p.S293= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV66760712; called by muse, mutect2
- CLEC4F | c.1731C>T p.F577= | Silent (SNP) | VAF 56/136 reads (41%) | catalogued as COSV55479716; called by muse, mutect2, varscan2
- CLRN1 | c.351C>A p.A117= (on ENST00000327047 / NM_174878.3; = p.A41= on NM_052995.2) | Silent (SNP) | VAF 35/147 reads (24%) | catalogued as COSV55805723; called by muse, mutect2, varscan2
- COL11A1 | c.1566G>A p.Q522= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV62185033; called by muse, mutect2, varscan2
- CST1 | c.423C>A p.S141= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100494401, COSV59055529; called by muse, mutect2, varscan2
- DVL2 | c.321G>C p.R107= | Silent (SNP) | VAF 31/208 reads (15%) | catalogued as COSV50036398; called by muse, mutect2, varscan2
- ERICH3 | c.3978A>T p.T1326= | Silent (SNP) | VAF 139/416 reads (33%) | catalogued as rs1267698153, COSV58608341; called by muse, mutect2, varscan2
- FAM160B1 | c.519A>G p.L173= | Silent (SNP) | VAF 101/383 reads (26%) | catalogued as COSV65086562; called by muse, varscan2
- FANCA | c.1014T>C p.D338= | Silent (SNP) | VAF 30/161 reads (19%) | catalogued as COSV66881795; called by muse, mutect2, varscan2
- FBXO21 | c.894A>T p.T298= | Silent (SNP) | VAF 43/150 reads (29%) | catalogued as COSV57973130; called by muse, mutect2, varscan2
- GPNMB | c.498C>T p.P166= | Silent (SNP) | VAF 127/357 reads (36%) | catalogued as rs767032879, COSV51698912; called by muse, mutect2, varscan2
- GRIA2 | c.954A>G p.R318= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as rs1334692207, COSV52392296, COSV52396577; called by muse, mutect2, varscan2
- GRK4 | c.1008G>A p.E336= (on ENST00000398052 / NM_182982.3; = p.E304= on NM_005307.3) | Silent (SNP) | VAF 85/263 reads (32%) | catalogued as COSV61669465; called by muse, mutect2, varscan2
- HECW1 | c.2274G>A p.L758= | Silent (SNP) | VAF 62/177 reads (35%) | catalogued as COSV67830913; called by muse, mutect2, varscan2
- KDM3B | c.963A>G p.R321= | Silent (SNP) | VAF 82/281 reads (29%) | catalogued as COSV58691112; called by muse, mutect2, varscan2
- KNG1 | c.1095C>T p.Y365= | Silent (SNP) | VAF 129/476 reads (27%) | catalogued as rs775898867, COSV53978339; called by muse, mutect2, varscan2
- MAML2 | c.1635G>T p.P545= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV73263655; called by muse, mutect2, varscan2
- MINDY1 | c.921G>A p.K307= | Silent (SNP) | VAF 328/821 reads (40%) | catalogued as COSV56499093; called by muse, mutect2, varscan2
- MMP1 | c.402T>A p.I134= | Silent (SNP) | VAF 111/506 reads (22%) | catalogued as COSV59510561; called by muse, mutect2, varscan2
- NPSR1 | c.435C>T p.D145= | Silent (SNP) | VAF 49/381 reads (13%) | catalogued as COSV62201454; called by muse, mutect2, varscan2
- OR2AG1 | c.639T>A p.A213= | Silent (SNP) | VAF 82/341 reads (24%) | catalogued as COSV56626278; called by muse, mutect2, varscan2
- OR2B6 | c.339T>C p.L113= | Silent (SNP) | VAF 22/208 reads (11%) | catalogued as COSV55129031; called by muse, mutect2
- OR2M5 | c.543C>T p.F181= | Silent (SNP) | VAF 119/1070 reads (11%) | catalogued as rs529569358, COSV63546378; called by muse, varscan2
- OR4C6 | c.207C>A p.V69= | Silent (SNP) | VAF 96/421 reads (23%) | catalogued as COSV58604335; called by muse, mutect2, varscan2
- PCDH15 | c.4662C>T p.P1554= | Silent (SNP) | VAF 48/283 reads (17%) | catalogued as COSV57321648; called by muse, mutect2, varscan2
- RABL3 | c.16C>A p.R6= | Silent (SNP) | VAF 28/218 reads (13%) | catalogued as rs376736040, COSV52204499; called by muse, mutect2, varscan2
- ROBO4 | c.666G>A p.R222= | Silent (SNP) | VAF 68/275 reads (25%) | catalogued as COSV60624577; called by muse, mutect2, varscan2
- RXFP3 | c.639G>T p.S213= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs200520186, COSV57505994; called by muse, mutect2, varscan2
- SDS | c.432C>T p.G144= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV57453688; called by muse, mutect2, varscan2
- TBX20 | c.1230C>A p.G410= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV68783138, COSV68783865; called by muse, mutect2, varscan2
- TCERG1L | c.642G>A p.T214= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs757941970, COSV64046599, COSV64050809; called by muse, mutect2, varscan2
- TNFSF4 | c.477C>T p.S159= | Silent (SNP) | VAF 29/291 reads (10%) | catalogued as COSV56056667; called by muse, mutect2, varscan2
- TOP2B | c.177A>C p.T59= (on ENST00000264331 / NM_001330700.2; = p.T54= on NM_001068.3) | Silent (SNP) | VAF 75/257 reads (29%) | catalogued as COSV51972659; called by muse, mutect2, varscan2
- TRIM58 | c.807C>T p.I269= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV63570539; called by muse, mutect2, varscan2
- TSHZ2 | c.2319G>A p.K773= | Silent (SNP) | VAF 97/334 reads (29%) | catalogued as COSV61589086; called by muse, mutect2, varscan2
- TTC25 | c.1452C>T p.D484= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs370439442; called by muse, mutect2, varscan2
- TTN | c.83217C>T p.G27739= (on ENST00000591111; = p.G20315= on NM_003319.4) | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV60104277, COSV60176545; called by muse, mutect2, varscan2
- URB2 | c.327G>A p.E109= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV50994551; called by muse, mutect2
- USH2A | c.12774A>G p.T4258= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as COSV56378196; called by muse, mutect2, varscan2
- ZBTB39 | c.687C>T p.L229= | Silent (SNP) | VAF 21/180 reads (12%) | catalogued as COSV55629549; called by muse, mutect2, varscan2
- ZFPM2 | c.3132G>A p.V1044= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV65873926; called by muse, mutect2, varscan2
- ZNRF3 | c.843C>T p.A281= (on ENST00000544604 / NM_001206998.2; = p.A181= on NM_032173.3) | Silent (SNP) | VAF 387/943 reads (41%) | catalogued as COSV60434812; called by muse, mutect2, varscan2
- NT5C1B-RDH14 | c.*67G>A | 3'UTR (SNP) | VAF 113/327 reads (35%) | catalogued as COSV67119089; called by muse, mutect2, varscan2
- PDLIM5 | c.920+615G>T | Intron (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100523430, COSV58750694; called by muse, mutect2, varscan2
- ZNF688 | c.-608G>C | 5'UTR (SNP) | VAF 15/95 reads (16%) | catalogued as COSV99794118; called by muse, mutect2, varscan2
